Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6516, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6516-01A (Primary Tumor).

TCGA-D6-6516

Material: Lesion excision – tumor of the lower lip

Physician in charge:

Material collected: Material received on:

Expected time of examination:

Clinical diagnosis: Tumour of the lower lip

Examination performed on:

Macroscopic description:

Partial resection of the lower lip, specimens sized 1.5 x 2.0 x 1.0 cm containing papillar tumor sized 1.5 x 1.0 x 0.5 cm.

Microscopic description:

Carcinoma planoepitheliale keratodes G2. The largest diameter of the tumor: 1.5cm. Minimal margin of the normal tissue from the lateral side of the resected material: 2mm. Minimal margin of the normal tissue from the bottom of the resected material: 1.5mm

Histopathological diagnosis:

Carcinoma planoepitheliale keratodes cutis. G2; pT1. Invasive planoepithelial carcinoma keratodes of the skin

Excision lines within healthy tissues.

Source: NCI Genomic Data Commons file 4d4b4ee9-2edc-4671-8683-cc6877e30538 (TCGA-D6-6516.65875EA2-303E-4FF8-A969-5F1E6BCE5961.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).